Somatic mutation profile of tumor specimen TCGA-CV-7415-01A (aliquot TCGA-CV-7415-01A-11D-2078-08) from TCGA case TCGA-CV-7415, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.4 years (22,062 days).
Specimen TCGA-CV-7415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68e656f4-a989-4e22-bb57-6adbf477035d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7415-10A (Blood Derived Normal), aliquot TCGA-CV-7415-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07a06b0a-fcdb-4fdf-8a7e-3d2528bf3a5a

The open-access MAF lists 83 somatic variants for this specimen: 56 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 24, Nonsense Mutation 3, Intron 3, Translation Start Site 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TACR3 | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | catalogued as rs760022956, CS104228, COSV59199949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- AGO2 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1308828307, COSV55045218; called by muse, mutect2, varscan2
- ANKRD17 | c.6313C>G p.H2105D | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.112); catalogued as COSV100429814; called by muse, mutect2
- APBB1IP | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100774440; called by muse, mutect2, varscan2
- BAZ1A | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100701202; called by muse, mutect2
- BTG3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100336362; called by muse, mutect2, varscan2
- CCDC171 | c.3679C>T p.H1227Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV101048596, COSV104432689; called by muse, mutect2, varscan2
- CD163L1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.174); catalogued as rs760155715, COSV58021752; called by muse, mutect2, varscan2
- CDC73 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100813960; called by muse, mutect2, varscan2
- CDHR2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99992061; called by muse, varscan2
- CMTR2 | c.1264A>T p.K422* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100579313, COSV57605027; called by mutect2, varscan2
- COL5A2 | c.4471G>A p.V1491I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs200703515, COSV66410849; ClinVar: uncertain significance; called by mutect2, varscan2
- CTNNA3 | c.2341A>T p.I781F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101041549; called by muse, mutect2, varscan2
- DHODH | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99536980; called by muse, mutect2, varscan2
- DNAH9 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV99307524; called by muse, mutect2
- DUOX1 | c.2257G>T p.A753S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100368354; called by muse, mutect2, varscan2
- F12 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499886; called by muse, mutect2, varscan2
- FBH1 | c.563G>A p.G188D (on ENST00000362091 / NM_178150.3; = p.G239D on NM_032807.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV100758896; called by muse, mutect2, varscan2
- FGD1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs199677604, COSV100911231; called by muse, varscan2
- FTL | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 77/135 reads (57%) | catalogued as COSV99509205; called by muse, mutect2, varscan2
- GPR174 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs902315180, COSV99338328; called by muse, mutect2, varscan2
- HECTD1 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101237476; called by muse, mutect2, varscan2
- JMJD1C | c.1337C>G p.A446G | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101232457; called by muse, mutect2, varscan2
- LILRA5 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs369179682; called by muse, mutect2
- MAGI3 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs767631910, COSV56826941; called by muse, mutect2, varscan2
- MDGA2 | c.1293A>T p.E431D (on ENST00000399232 / NM_001113498.2; = p.E133D on NM_182830.4) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.747); catalogued as rs924969864, COSV62116254; called by muse, mutect2, varscan2
- MMP14 | c.1119G>C p.E373D | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100314289; called by muse, mutect2
- MSLN | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV99558606; called by muse, varscan2
- MUC16 | c.32710G>A p.E10904K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV101201046; called by muse, mutect2, varscan2
- NMT1 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99364943; called by muse, mutect2
- OR2M3 | c.533T>C p.F178S | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV101513502; called by muse, mutect2, varscan2
- OR2M7 | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100522656; called by muse, mutect2
- PABPC5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); catalogued as COSV100442633; called by muse, mutect2, varscan2
- PCDH10 | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52090033, COSV99994288; called by muse, mutect2, varscan2
- PCDHGC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452697214, COSV52744109; called by muse, mutect2, varscan2
- PHYKPL | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100069660; called by muse, mutect2, varscan2
- PKHD1L1 | c.3571G>T p.E1191* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV101006684, COSV65745011; called by muse, mutect2, varscan2
- PLAC1 | c.294A>G p.I98M | Missense Mutation (SNP) | VAF 86/109 reads (79%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV100821624; called by muse, mutect2, varscan2
- PSG6 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99414430; called by muse, mutect2, varscan2
- RABGAP1L | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99273425; called by muse, mutect2, varscan2
- RPLP0 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV99935442; called by muse, mutect2, varscan2
- SBNO1 | c.1330T>G p.L444V (on ENST00000420886; = p.L443V on NM_018183.5) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV57338899; called by muse, mutect2, varscan2
- SLC27A5 | c.1418C>A p.A473E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV99564288, COSV99564575; called by muse, mutect2, varscan2
- SLC35G2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101262086; called by muse, mutect2, varscan2
- SLC9A4 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99763431; called by muse, mutect2, varscan2
- STX18 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100086354; called by muse, varscan2
- TAF5 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100674752; called by muse, mutect2
- TCHHL1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs762995314, COSV100916584; called by muse, mutect2
- THAP5 | c.1183A>T p.I395L (on ENST00000415914 / NM_001130475.3; = p.I353L on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100542880; called by muse, mutect2
- TLE4 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54627080; called by muse, mutect2, varscan2
- TTN | c.17867T>C p.V5956A (on ENST00000591111; = p.V5029A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | PolyPhen benign (0.003); catalogued as COSV60000314; called by muse, mutect2, varscan2
- ZNF804A | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100169636; called by muse, mutect2, varscan2
- PEX2 | c.758dup p.M253Ifs*8 | Frame Shift Ins (INS) | VAF 49/133 reads (37%) | called by mutect2, pindel, varscan2
- RIPK4 | c.1694_1705del p.E565_R569delinsG (on ENST00000352483; = p.E517_R521delinsG on NM_020639.3) | In Frame Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- SRSF10 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- APBB1 | c.741C>T p.N247= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs775496229, COSV100194329, COSV54981827; called by muse, mutect2, varscan2
- ASPM | c.123C>G p.L41= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99660934; called by muse, mutect2, varscan2
- BRAP | c.1494A>G p.R498= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV100554234; called by muse, mutect2, varscan2
- CDT1 | c.1419C>G p.L473= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99967347; called by muse, mutect2
- CFAP45 | c.444C>A p.I148= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100928651; called by muse, mutect2, varscan2
- CNTRL | c.309G>C p.L103= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV53049835, COSV99443417; called by muse, mutect2
- FBN2 | c.8385G>A p.E2795= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV52498838, COSV99330008; called by muse, mutect2, varscan2
- FSTL5 | c.84T>C p.Y28= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs777162582, COSV100059857; called by muse, mutect2, varscan2
- GALNT8 | c.1164T>C p.L388= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99363152; called by muse, mutect2
- GRID1 | c.1176C>G p.V392= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100025946; called by muse, mutect2, varscan2
- LAMB4 | c.213C>T p.I71= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99225260; called by muse, varscan2
- MCF2L2 | c.1239C>T p.I413= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV61053054; called by muse, mutect2, varscan2
- MECOM | c.453C>T p.R151= (on ENST00000468789 / NM_001105078.4; = p.R339= on NM_004991.4) | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV99245194; called by muse, mutect2, varscan2
- MTUS2 | c.669C>T p.H223= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs781473869, COSV101462337; called by muse, mutect2
- MYO16 | c.198C>T p.D66= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1317266812, COSV51794968, COSV99194411; called by muse, mutect2, varscan2
- MYO5B | c.4383G>A p.R1461= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99546061; called by muse, mutect2, varscan2
- PARD3 | c.3588G>A p.S1196= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs200437339, COSV100632990; called by muse, varscan2
- PRAMEF1 | c.957C>G p.L319= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as COSV100180025; called by muse, mutect2, varscan2
- PRAMEF12 | c.1026G>A p.L342= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV63215708; called by muse, mutect2, varscan2
- PRUNE2 | c.5649T>C p.Y1883= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV100945017; called by muse, mutect2, varscan2
- SELE | c.441C>T p.S147= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV60974142; called by muse, mutect2, varscan2
- SETD6 | c.465C>T p.H155= (on ENST00000219315 / NM_001160305.4; = p.H131= on NM_024860.3) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99262479; called by muse, mutect2
- TRPM2 | c.3102C>G p.L1034= | Silent (SNP) | VAF 41/377 reads (11%) | catalogued as COSV100309207; called by muse, mutect2, varscan2
- WAPL | c.1467G>A p.Q489= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV53937975; called by muse, mutect2, varscan2
- ANK3 | c.2615-1266G>C | Intron (SNP) | VAF 22/114 reads (19%) | catalogued as COSV99781781; called by muse, mutect2, varscan2
- EIF6 | c.107+54A>C | Intron (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100981653; called by muse, mutect2, varscan2
- MYH7B | c.2100+126_2100+145del | Intron (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
